Somatic mutation profile of tumor specimen PCProject_0035_T1_WES (aliquot PCProject_0035_T1_WES_1) from CMI case PCProject_0035, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.4 years (26,819 days).
Specimen PCProject_0035_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a495fbe6-d511-4317-95fc-4745807c039a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0035_SALIVA (Saliva), aliquot PCProject_0035_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104bc507-3033-4ab8-b51b-b53a6577cdb4

The open-access MAF lists 61 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, 3'UTR 5, Frame Shift Del 4, 5'UTR 3, Intron 2, Nonsense Mutation 1, 3'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- B3GNT6 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs1555027758; called by muse, mutect2, varscan2
- CACNA1E | c.6149G>A p.R2050H (on ENST00000367573 / NM_001205293.3; = p.R2007H on NM_000721.4) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs775134582, COSV62398327; called by muse, mutect2, varscan2
- CDH8 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771617779, COSV54865437; called by muse, mutect2, varscan2
- CHAF1B | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs1172957320, COSV100023283; called by muse, mutect2, varscan2
- GRM1 | c.3106G>A p.G1036R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.36); catalogued as rs1160404247, COSV51184080; called by muse, mutect2, varscan2
- KDM3A | c.2422G>C p.G808R | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV57220255; called by muse, mutect2, varscan2
- KHDRBS2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs374827571; called by muse, mutect2, varscan2
- MUC16 | c.27274G>T p.G9092C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs990340888; called by muse, mutect2, varscan2
- NDC80 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs371134043; called by muse, mutect2, varscan2
- PLD1 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757887725; called by muse, varscan2
- USH2A | c.13599del p.M4535Wfs*15 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as COSV56327484; called by mutect2, pindel, varscan2
- ADGRD1 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CCDC121 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CHD3 | c.1499G>T p.C500F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- CLTB | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 77/348 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CSF1R | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- CUL9 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMNL2 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- GOLGA6L22 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IER3 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- IL6ST | c.333del p.E112Nfs*9 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- MGA | c.7478_7486del p.N2493_L2495del (on ENST00000219905 / NM_001164273.1; = p.N2284_L2286del on NM_001080541.2) | In Frame Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- MYH8 | c.5121G>T p.Q1707H | Missense Mutation (SNP) | VAF 119/373 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PGR | c.2182T>C p.S728P | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PTEN | c.227_234del p.Y76Cfs*4 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- PTGS1 | c.1127T>A p.I376N | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3575A>G p.K1192R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RPL11 | c.329A>T p.E110V (on ENST00000374550 / NM_001199802.1; = p.E111V on NM_000975.5) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SAV1 | c.189_192del p.G64Mfs*2 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- SPAG17 | c.4597C>A p.P1533T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2
- UHRF1 | c.714G>T p.W238C (on ENST00000612630 / NM_001290050.1; = p.W251C on NM_013282.4) | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX3 | c.9143A>G p.H3048R | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF268 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF462 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZNF541 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA13 | c.12129C>T p.R4043= | Silent (SNP) | VAF 44/228 reads (19%) | catalogued as rs751562649, COSV71290250; called by muse, mutect2, varscan2
- ADCY7 | c.954C>T p.N318= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs758374570; called by muse, mutect2, varscan2
- BCL11B | c.1932C>T p.D644= (on ENST00000357195 / NM_001282237.2; = p.D573= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1461890836; called by muse, mutect2, varscan2
- BTAF1 | c.3798C>A p.L1266= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- CACNA1S | c.3399C>A p.I1133= | Silent (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2
- HPS5 | c.1908G>T p.L636= (on ENST00000349215 / NM_181507.2; = p.L522= on NM_007216.4) | Silent (SNP) | VAF 4/39 reads (10%) | called by mutect2, varscan2
- MYH6 | c.5538G>A p.E1846= | Silent (SNP) | VAF 66/245 reads (27%) | called by muse, mutect2, varscan2
- MYH7B | c.819C>T p.A273= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV53423641; called by muse, mutect2
- PRKD2 | c.1437C>T p.G479= | Silent (SNP) | VAF 85/351 reads (24%) | catalogued as COSV52185366; called by muse, mutect2, varscan2
- PRLR | c.1722A>G p.E574= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV99184869; called by muse, mutect2, varscan2
- RASSF10 | c.1389C>T p.C463= | Silent (SNP) | VAF 75/252 reads (30%) | called by muse, mutect2, varscan2
- SPPL2C | c.180C>T p.P60= | Silent (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- WDFY4 | c.2367G>A p.R789= | Silent (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- C2CD5 | c.-1C>G | 5'UTR (SNP) | VAF 69/241 reads (29%) | called by muse, mutect2, varscan2
- CALD1 | c.*238G>A | 3'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- CFL1 | c.-46C>G | 5'UTR (SNP) | VAF 26/92 reads (28%) | catalogued as rs1049294882; called by muse, mutect2, varscan2
- CLUHP11 | n.729C>T | RNA (SNP) | VAF 38/134 reads (28%) | catalogued as rs1323210821; called by muse, mutect2, varscan2
- DDX5 | c.-47C>T | 5'UTR (SNP) | VAF 79/317 reads (25%) | called by muse, mutect2, varscan2
- DNM2 | c.1672-2491G>T | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- EYA4 | chr6:133531246 C>T | 3'Flank (SNP) | VAF 24/90 reads (27%) | catalogued as rs570269258, COSV62050098; called by muse, mutect2, varscan2
- MOCS1 | c.*834A>T | 3'UTR (SNP) | VAF 87/283 reads (31%) | called by muse, mutect2, varscan2
- MPDU1 | c.*230C>T | 3'UTR (SNP) | VAF 67/251 reads (27%) | catalogued as rs1279146605; called by muse, mutect2, varscan2
- PLSCR3 | c.287-36G>C | Intron (SNP) | VAF 63/205 reads (31%) | called by muse, mutect2, varscan2
- SLC9A3R2 | c.*482_*485del | 3'UTR (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- XIAP | c.*5735G>C | 3'UTR (SNP) | VAF 19/29 reads (66%) | called by muse, varscan2
